Gene-level copy-number profile of tumor specimen MP2PRT-PASNVN-TMP1-A from MP2PRT case MP2PRT-PASNVN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,812 days).
Specimen MP2PRT-PASNVN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78cb3e8f-927d-42f9-b9ba-7a66a584ac6b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASNVN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/df3598a8-1f68-48db-8944-6dcef05ce42a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 534; copy number 1: 5,631; copy number 2: 51,619; copy number 3: 593.

Homozygous deletions (total copy number 0; autosomes only): 531 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,780,331–44,807,351, 4 genes: RPS15AP11, BEST4, PLK3, TCTEX1D4.
- chr1:171,101,728–171,101,806, 2 genes (within-gene range 0–2): MIR1295A, MIR1295B.
- chr2:88,811,186–89,254,015, 43 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr2:89,913,982–89,990,221, 9 genes: IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:113,325,372–113,425,548, 2 genes: AC016745.1, IGKV1OR2-108.
- chr6:102,453,367–120,015,257, 257 genes (within-gene range 0–2) (broad region; genes not listed).
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–2): TRGV5P, TRGV5.
- chr7:140,386,781–140,386,907, 1 gene (within-gene range 0–1): RNA5SP248.
- chr9:102,995,311–103,018,488, 1 gene: CYLC2.
- chr13:38,965,925–38,990,859, 1 gene: STOML3.
- chr13:61,997,136–62,029,572, 1 gene: LINC00358.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–1): TRDD1, TRDD2.
- chr14:105,672,308–106,631,653, 151 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–2): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–2): IGHV3-64, IGHV3-65, IGHVII-65-1.
- chr15:89,504,909–89,524,049, 2 genes (within-gene range 0–2): LINC00928, AC013391.3.
- chr22:22,032,745–22,245,515, 31 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,442. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
